Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WN-01A (Primary Tumor).

Gross:

Right adrenal tumor with the encapsulated tumor with total dimensions 75x60x30, weight 96 g, with soft consistency and with central white scar. In the peripheral part, non-tumoral adrenal with pressure atrophy with a cortex width less than 1 mm.

Micro:

Solidly and alveolarly and diffusely shaped pheochromocytoma with focal hemorrhages consisting polygonal and profoundly atrophied cells and focally spindle-formed cells. In some vessels in tumor periphery, a piece of freely laying tissue was found – probably a result of the procurement of soft tumor without previous fixation, this finding does not fulfill criteria of angioinvasion.

Immunohistochemistry:

Staining for S100 protein – sporadic sustentacular cells, large parts of the tumor are negative.

MIB 1 <2% positive cells.

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity 2

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 8

Procurement date:

Confirmation date:

ICD O-3

Pheochromocytoma,
malignant 8700/3
Site Adrenal gland NOS
174.9
9/10/13

Source: NCI Genomic Data Commons file dcea999f-8810-4946-bbde-e5d198a33c5b (TCGA-S7-A7WN.A5B5CBD5-998A-4A12-B453-BAB20E5A6CA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).